Gene-level copy-number profile of tumor specimen TCGA-CQ-5323-01A from TCGA case TCGA-CQ-5323, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 82.6 years (30,173 days).
Specimen TCGA-CQ-5323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.79dc8552-2a0e-48ab-82d1-ecd4623b6b1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-5323-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c2772b4-07f9-45ba-a820-b054dffdf9cd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 5,770; copy number 3: 5,694; copy number 4: 42,243; copy number 5: 1,464; copy number 6: 318; copy number 7: 2,456; copy number 8: 503; copy number 9: 744; copy number 10: 509; copy number 12: 72; copy number 14: 5; copy number 16: 4; copy number 17: 8; copy number 22: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-5323-01A-01D-1682-01): tumor purity 0.62, ploidy 3.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,362 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,250,858–197,302,519, 1 gene, copy number 10 (within-gene range 7–10): ANKRD44-IT1.
- chr2:197,311,393–199,471,266, 26 genes, copy number 10 (within-gene range 8–10): AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1.
- chr3:103,159,960–182,158,313, 1,283 genes, copy number 9–12 (broad region; genes not listed).
- chr11:62,208,673–62,426,724, 12 genes, copy number 9: SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2.
- chr11:68,754,620–68,940,602, 4 genes, copy number 16 (within-gene range 2–16): CPT1A, LINC02701, MRPL21, IGHMBP2.
- chr11:69,641,156–70,436,584, 27 genes, copy number 17–22: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 14–22: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr18:63,647,579–63,805,376, 3 genes, copy number 9 (within-gene range 4–9): SERPINB11, SERPINB3, SERPINB7.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
